MMRF case MMRF_1778 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/eed260ad-779e-468e-8313-9bde1f0d60c6

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 82 years; Vital status: Dead; Days to death: 19 days; Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 82.9 years (30,272 days); ISS stage: III; Days to last known disease status: 19 days; Days to last follow up: 19 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 1 day.

Follow-up (2 entries)
- Days to follow up: 0 days; ECOG performance status: 4.
- Follow-up contact recording only the day: day 19.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Albumin 28 g/L.
- Lactate Dehydrogenase 2.92 µkat/L.
- Hemoglobin 4.77 mmol/L.
- Serum Free Immunoglobulin Light Chain, Lambda 849 mg/dL.
- Beta 2 Microglobulin 6.01 µg/mL.
- Serum Free Immunoglobulin Light Chain, Kappa 0.81 mg/dL.
- Calcium 2.1 mmol/L.
- Platelets 98 ×10⁹/L.
- Total Protein 5.1 g/dL.
- Creatinine 601 µmol/L.
- Absolute Neutrophil 3 ×10⁹/L.
- M Protein 0.76 g/dL.
- Leukocytes 11 ×10⁹/L.
- Blood Urea Nitrogen 22.8 mmol/L.
- Glucose 6.33 mmol/L.

Other clinical attributes
- Day 0: Weight: 82 kg; Height: 165 cm.

Biospecimens (3 samples)
- Sample MMRF_1778_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 0 days.
- Sample MMRF_1778_1_PB_CD138pos: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
- Sample MMRF_1778_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
